Surgical pathology report (de-identified scan), TCGA case TCGA-44-2662, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-2662-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

- A. Lymph node level 10
- B. Right upper lobe
- C. Lymph node R4
- D. Lymph node level 7

CLINICAL NOTES

PRE-OP DIAGNOSIS: Right upper lobe lung cancer.

FROZEN SECTION DIAGNOSIS

FSB) Right upper lobe - Poorly differentiated non-small cell carcinoma. Bronchial margin is negative for tumor. [REDACTED]

GROSS DESCRIPTION

A. Received fresh, subsequently fixed in formalin labeled "level 10 lymph node" are multiple black-tan irregular rubbery tissue fragments which have an aggregate measurement of 2.5 x 1.5 x 0.7 cm. The specimens are entirely submitted in one cassette. AS-1.

B. Submitted fresh for tissue procurement labeled "right upper lobe of lung" consists of a lobe of lung tissue with an obvious large tumor mass present. The lobe measures maximally

15 x 9 x 8 cm. The portal surface is intact, though there are several areas of a fibrotic-like change present where the tumor mass appears

to approach the pleural surface. The larger of these is 5 cm in size. The smaller is 4 cm. The surrounding normal pleura is drawn into the edge of the sclerotic foci. Numerous white tapes with sutures are present at the point of transection of the lobe. It

has been amputated at the level of its main bronchus, which is stapled closed. Frozen section is obtained from the bronchial margin closest to that staple line. Sections into the lobe reveal the presence of a very large tumor mass occupying a large amount of the parenchyma. It measures 8 x 7 x 6 cm and is composed of spiculated

GROSS DESCRIPTION

dark tan-gray tumor with flecks of anthracotic pigment present within it. As noted above, it approached the pleura at least in two

different foci. Representative portion of the tumor is submitted for tissue procurement per request of [REDACTED]. A portion is also submitted for frozen section. Sections after fixation. [REDACTED]

Received fresh subsequently fixed in formalin labeled "lymph node R4". The specimen consists of multiple brown-tan irregular rubbery tissue fragments which have an aggregate measurement of 3.5 x 3.0 x 0.7 cm. The specimens are entirely submitted in one cassette. [REDACTED]

[page 2 of 2]
-
- D. Received fresh subsequently fixed in formalin labeled "lymph node level 7" are multiple black-tan-yellow irregular rubbery to soft tissue fragments which have an aggregate measurement of 2.5 x 2.0 x 0.8 cm. The specimens are entirely submitted in one cassette. AS-1.
-
-

MICROSCOPIC DESCRIPTION

Histologic type: Non-small cell carcinoma.
Histologic grade: Poorly differentiated.
Primary tumor (pT): Tumor measures maximally 8 cm. in greatest extent and does not involve the visceral pleural surface (pT2).
Margins of resection: Negative.
Direct extension of tumor: Absent.
Venous (large vessel) invasion: Negative.
Arterial (large vessel) invasion: Negative.
Lymphatic (small vessel) invasion: Negative.
Regional lymph nodes (pN): Mediastinal lymph nodes level 10, R4 and level 7 are all negative for metastatic carcinoma (pN0).
Distant metastasis (pM): Could not be assessed (pMx).

5, 3x3

DIAGNOSIS

- A. Lymph node, level 10, resection:
Negative for metastatic carcinoma.
- B. Lung, right upper lobectomy:
Invasive poorly differentiated non-small cell carcinoma.
Visceral pleural surface, vascular and bronchial margins of resection are free of involvement by tumor.
- C. Lymph node, R4, resection:
Negative for metastatic carcinoma.
- D. Lymph node, level 7, resection:
Negative for metastatic carcinoma.
-

Source: NCI Genomic Data Commons file 70b83a66-f8b8-4678-9cf3-8850c7a122d0 (TCGA-44-2662.76BAB538-E95A-48A6-9F83-36B9A472252B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).